CGCI case BLGSP-71-23-00593 — Burkitt Lymphoma Genome Sequencing Project (CGCI-BLGSP)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature B-Cell Lymphomas; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/08ecccb7-db6b-435a-a64b-86be8be343ef

Demographics
Sex at birth: male; Race: white; Age at index: 9 years.

Diagnoses (1)
1. Burkitt lymphoma, NOS (Includes all variants): ICD-O-3 morphology code: 9687/3; Tissue or organ of origin: Hematopoietic system, NOS; Classification of tumor: primary; Age at diagnosis: 9.9 years (3,603 days); Year of diagnosis: 2010; Method of diagnosis: Incisional Biopsy; Ann Arbor pathologic stage: Stage III; Ann Arbor B symptoms: Yes; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 1,926 days (5.3 years); Ann Arbor extranodal involvement: Yes; Max tumor bulk site: Ascites/peritoneum; Sites of involvement: Peritoneum, NOS.
   Pathology details: Bone marrow malignant cells: No; Lymph node involved site: Retroperitoneal.
   Pathology details: Lymph node involved site: Splenic.
   Treatment given: Treatment type: Chemotherapy; Initial disease status: Initial Diagnosis; Regimen or line of therapy: BFM-95; Days to treatment start: 1 day; Days to treatment end: 167 days; Number of cycles: 6; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cytarabine + Dexamethasone + Methotrexate + Rituximab + Vincristine; Initial disease status: Initial Diagnosis; Days to treatment start: 1 day; Days to treatment end: 167 days; Number of cycles: 6; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Chemotherapy; Initial disease status: Initial Diagnosis; Days to treatment start: 1 day; Days to treatment end: 167 days; Number of cycles: 6; Treatment outcome: Complete Response.
   Recorded as not given: neoadjuvant treatment (type not reported), for initial diagnosis; adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.

Follow-up (2 entries)
- Days to follow up: 0 days; Karnofsky performance status: 90; ECOG performance status: 1.
- Days to follow up: 1,926 days (5.3 years); Disease response: Tumor Free.

Molecular and laboratory tests
- BCL2 (IHC): Negative.
- BCL6 (IHC): Positive; Specialized molecular test: BCL6 > 30%.
- CD10 (IHC): Positive; Specialized molecular test: CD10 > 30%.
- CD20 (IHC): Positive.
- CD3 (IHC): Negative.
- Ki67 (IHC): Positive; Specialized molecular test: Ki-67 > 90%.
- MYC translocation (FISH): Negative.
- Epstein-Barr Virus: Negative.
- Lactate Dehydrogenase 1420 [Blood test normal range upper: 618].

Other clinical attributes
- Day 0: Comorbidities: Autoimmune Lymphoproliferative Syndrome (ALPS).
- Day 0: Weight: 31.5 kg; Height: 125 cm; BMI: 20.2.
- Day 0: Risk factors: Autoimmune Lymphoproliferative Syndrome (ALPS).
- Day 0: Risk factor treatment: Yes.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample BLGSP-71-23-00593-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Tissue collection type: Retrospective.
- Sample BLGSP-71-23-00593-01Z: Sample type: Tumor; Tissue type: Tumor.
  Slide BLGSP-71-23-00593-01-BCL6: Tissue microarray coordinates: B2,A3,C5.
  Slide BLGSP-71-23-00593-01-CD3: Tissue microarray coordinates: B2,A3,C5.
  Slide BLGSP-71-23-00593-01-Ki67: Tissue microarray coordinates: B2,A3,C5.
  Slide BLGSP-71-23-00593-01-CD10: Tissue microarray coordinates: B2,A3,C5.
  Slide BLGSP-71-23-00593-01-CD20: Tissue microarray coordinates: B2,A3,C5.
  Slide BLGSP-71-23-00593-01-BCL2: Tissue microarray coordinates: B2,A3,C5.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: Tumor free; Treatment outcome first course: Complete Remission/Response; Lost to follow-up: No; New tumor event diagnosis indicator: No.
- History of disease: History immunological disease other: Alps; History immunosuppressive prescription other: Predinisone.
- Primary pathology: Histologic diagnosis: Burkitt lymphoma (BL), classic morphology; Lymph nodes examined: No.
- Stage record, Ann arbor: B symptoms present indicator: Yes.
- Tests performed: LDH level: 1420; Immunophenotypic analysis method: Immunohistochemistry.
- Follow-up form: Tumor status: Tumor free; Treatment outcome at TCGA followup: Complete Remission/Response; New tumor event diagnosis indicator: No.
- Treatments, Treatment: Therapy regimen: Initial; Chemo end reporting period: Yes; Pharmaceutical regimen: Other Pharmaceutical Regimen (please specify); Pharma adjuvant cycles count: 6.
